Somatic mutation profile of tumor specimen BA2195D (aliquot aq-BA2195D) from BEATAML1.0 case 2013, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated CEBPA; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.4 years (24,977 days).
Specimen BA2195D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 62a269c2-3683-4091-9fb4-ae936e27f30f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2318D (Solid Tissue Normal), aliquot aq-BA2318D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/31e3de8d-510e-42d0-8eb0-32bb4e197bf2

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MPL | c.1514G>A p.S505N | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs121913614, CM041395, COSV65244631; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- TP53 | c.452C>G p.P151R | Missense Mutation (SNP) | VAF 24/48 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057520000, COSV52677206, COSV52707835, COSV52811105; ClinVar: likely pathogenic / uncertain significance; called by muse, varscan2
- DISP3 | c.1306C>A p.Q436K | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.466); catalogued as COSV53825250, COSV99609133; called by muse, mutect2
- G2E3 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.055); catalogued as rs139585540; called by muse, mutect2, varscan2
- TENM3 | c.4486C>T p.R1496W | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs781047746, COSV69299757; called by muse, mutect2, varscan2
- DCDC1 | c.1871G>T p.C624F | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.434); called by muse, mutect2
- HES1 | c.303C>A p.S101R | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2
- KBTBD11 | c.89C>A p.P30Q | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); called by muse, mutect2
- RAB33B | c.272G>A p.G91E | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- BTAF1 | c.918C>A p.G306= | Silent (SNP) | VAF 16/102 reads (16%) | called by mutect2, varscan2
- GALNT9 | c.1077+37G>A | Intron (SNP) | VAF 30/93 reads (32%) | called by muse, mutect2, varscan2
